Somatic mutation profile of tumor specimen 0D8XGH from CCDI case PBBIBR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.9 years (4,702 days).
Specimen 0D8XGH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0255f410-94fd-4b73-8ed6-630d6721f22b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8XGI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3359543-f30e-4606-8864-f3217cc91efd

The open-access MAF lists 39 somatic variants for this specimen: 28 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 4, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Splice Site 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC4 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 52/372 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs762541691; called by muse, varscan2
- C1S | c.717+4C>T | Splice Region (SNP) | VAF 44/171 reads (26%) | catalogued as rs782020836; called by muse, mutect2, varscan2
- CASKIN1 | c.772C>G p.L258V | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58876521; called by muse, mutect2, varscan2
- CCN5 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs1408308227; called by muse, mutect2, varscan2
- CD93 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 58/285 reads (20%) | catalogued as rs757186357; called by muse, mutect2, varscan2
- IL9R | c.1171G>T p.D391Y | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs773150888; called by muse, varscan2
- MYCN | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV99808391; called by muse, mutect2, varscan2
- MYLK | c.4763C>T p.P1588L | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60612081; called by muse, mutect2, varscan2
- RFTN1 | c.827-1G>T p.X276_splice | Splice Site (SNP) | VAF 5/89 reads (6%) | catalogued as COSV61917131; called by muse, mutect2
- TRPC4AP | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 95/453 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs367704685; called by muse, mutect2, varscan2
- ANKRD17 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD31 | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATAD3B | c.577C>T p.H193Y (on ENST00000308647; = p.H299Y on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DMXL1 | c.34A>T p.N12Y | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, varscan2
- FBN2 | c.6521A>G p.E2174G | Missense Mutation (SNP) | VAF 90/228 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLYATL1B | c.434A>G p.N145S | Missense Mutation (SNP) | VAF 33/404 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.044); called by muse, mutect2
- HRNR | c.6985G>A p.G2329S | Missense Mutation (SNP) | VAF 35/954 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2
- KNDC1 | c.1525T>C p.S509P | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- MRPL10 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 90/468 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTBP | c.1567C>G p.L523V | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- OBP2B | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR10K1 | c.157A>T p.R53* | Nonsense Mutation (SNP) | VAF 67/259 reads (26%) | called by muse, mutect2, varscan2
- OR52H1 | c.691C>A p.P231T (on ENST00000322653; = p.P237T on NM_001005289.1) | Missense Mutation (SNP) | VAF 27/267 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- RNF39 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SUCO | c.1736_1757del p.Q579Rfs*8 | Frame Shift Del (DEL) | VAF 51/335 reads (15%) | called by mutect2, pindel, varscan2
- THUMPD2 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSPOAP1 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 66/417 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by mutect2, varscan2
- WDR31 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAB2IP | c.2439C>T p.S813= (on ENST00000408936; = p.S785= on NM_032552.3) | Silent (SNP) | VAF 19/179 reads (11%) | catalogued as rs1384724986; called by muse, mutect2, varscan2
- GP1BA | c.366C>T p.D122= | Silent (SNP) | VAF 55/372 reads (15%) | catalogued as rs781353131, COSV56700348; called by muse, mutect2, varscan2
- MAL | c.165G>C p.V55= | Silent (SNP) | VAF 72/282 reads (26%) | called by muse, mutect2, varscan2
- SLC13A2 | c.486G>A p.S162= | Silent (SNP) | VAF 85/398 reads (21%) | catalogued as rs782322155, COSV100120181; called by muse, mutect2, varscan2
- STPG2 | c.1083A>T p.S361= | Silent (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.2817+26T>A | Intron (SNP) | VAF 29/120 reads (24%) | called by muse, varscan2
- MAGED1 | c.45+338C>T | Intron (SNP) | VAF 43/99 reads (43%) | called by muse, mutect2, varscan2
- MAN2A2 | c.*24A>G | 3'UTR (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- NEB | c.8890-2835C>T | Intron (SNP) | VAF 52/169 reads (31%) | catalogued as rs1401570716; called by muse, mutect2, varscan2
- OR2T2 | c.-13C>A | 5'UTR (SNP) | VAF 56/318 reads (18%) | catalogued as rs367832766; called by muse, mutect2
- SH3YL1 | c.291+4735C>G | Intron (SNP) | VAF 37/359 reads (10%) | called by muse, mutect2, varscan2
